Somatic mutation profile of tumor specimen ALCH-AEEK-TTP1-A (aliquot ALCH-AEEK-TTP1-A-1-0-D-A618-36) from ALCHEMIST case ALCH-AEEK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.5 years (26,464 days).
Specimen ALCH-AEEK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c7fd4a5-867c-4b39-b1b9-7248a70e4b25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEEK-NB1-A (Blood Derived Normal), aliquot ALCH-AEEK-NB1-A-1-0-D-A618-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df31205e-c704-45d1-93e7-d38649dc7c7a

The open-access MAF lists 566 somatic variants for this specimen: 389 protein-altering or splice-affecting, 116 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 332, Silent 116, Nonsense Mutation 27, Intron 25, Frame Shift Del 15, RNA 14, Splice Site 10, 3'UTR 9, 5'Flank 6, 5'UTR 6, Nonstop Mutation 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 70/242 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58051056; called by muse, mutect2, varscan2
- ACKR2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.185); catalogued as rs761336289; called by muse, mutect2, varscan2
- ADAMTS20 | c.500T>C p.I167T | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs765962045; called by muse, mutect2, varscan2
- ADGRG4 | c.7156T>C p.C2386R | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99795759; called by muse, mutect2, varscan2
- ADGRL4 | c.604G>T p.V202F | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV66061841; called by muse, mutect2, varscan2
- ADIPOQ | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as COSV57859315; called by muse, mutect2, varscan2
- AMOTL2 | c.509A>T p.N170I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1272736075; called by mutect2, varscan2
- ANK1 | c.2930C>T p.A977V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV55889996; called by muse, mutect2, varscan2
- ANKFN1 | c.2007T>A p.D669E | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs749440920; called by muse, mutect2, varscan2
- APOH | c.200C>G p.P67R | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as rs567530022; called by muse, mutect2, varscan2
- AQP4 | c.510G>C p.L170F | Missense Mutation (SNP) | VAF 25/569 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV101270568; called by muse, mutect2
- ARF1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.253); catalogued as COSV55255704; called by muse, mutect2, varscan2
- B3GALNT1 | c.457A>G p.N153D | Missense Mutation (SNP) | VAF 99/360 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1451301662; called by muse, mutect2, varscan2
- BLK | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755705290; called by muse, mutect2, varscan2
- BPIFB6 | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100848496; called by muse, mutect2, varscan2
- BRINP1 | c.1774C>A p.L592I | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.522); catalogued as COSV56292112, COSV56302727; called by muse, mutect2
- C12orf60 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 91/284 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV57452569; called by muse, mutect2, varscan2
- C6orf15 | c.606G>T p.R202S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as rs1300339673; called by muse, mutect2, varscan2
- CA14 | c.72T>A p.Y24* | Nonsense Mutation (SNP) | VAF 72/402 reads (18%) | catalogued as rs782688929; called by muse, mutect2, varscan2
- CACNA2D4 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.995); catalogued as rs755538838; called by muse, mutect2, varscan2
- CCDC181 | c.1003C>A p.L335I | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV63156451; called by muse, mutect2, varscan2
- CD38 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 83/309 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV56891641; called by muse, mutect2, varscan2
- CDC42BPG | c.2629G>T p.G877C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1308769006, COSV100712075; called by muse, mutect2
- CDH2 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs199882009, COSV52274643; called by muse, mutect2, varscan2
- CLEC9A | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as COSV59531490; called by muse, mutect2
- CNTN5 | c.173C>A p.S58* | Nonsense Mutation (SNP) | VAF 63/1148 reads (5%) | catalogued as COSV54278989; called by muse, mutect2
- COL22A1 | c.2290C>A p.P764T | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1280843879; called by muse, mutect2, varscan2
- COL5A2 | c.3448C>G p.L1150V | Missense Mutation (SNP) | VAF 141/330 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100880663; called by muse, mutect2, varscan2
- CPQ | c.308T>G p.V103G | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55149087; called by muse, mutect2
- CSMD3 | c.2060G>A p.R687K (on ENST00000297405 / NM_001363185.1; = p.R583K on NM_052900.3) | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); catalogued as COSV52184449; called by muse, mutect2
- DACH1 | c.1632G>T p.M544I (on ENST00000619232 / NM_001366712.1; = p.M492I on NM_080759.6) | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV57493671; called by muse, mutect2, varscan2
- DHRS7C | c.587A>G p.K196R (on ENST00000330255 / NM_001220493.2; = p.K195R on NM_001105571.3) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100364698; called by muse, mutect2, varscan2
- DLC1 | c.637A>G p.T213A | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV52328056; called by muse, mutect2
- DLG2 | c.1621G>T p.V541F | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54646625; called by muse, mutect2, varscan2
- DNAH9 | c.4364C>A p.P1455Q | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as COSV52348811; called by muse, mutect2, varscan2
- DOK7 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs144269117; called by muse, mutect2, varscan2
- DSEL | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.191); catalogued as rs1290270810, COSV100025212; called by muse, mutect2
- EP400 | c.5164G>A p.E1722K | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs1226408837; called by muse, mutect2
- ERBB2 | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as rs531563820, COSV99068585, COSV99508787; called by muse, mutect2, varscan2
- FAM43B | c.824C>A p.A275E | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1190416146; called by muse, mutect2, varscan2
- FAT1 | c.2194G>T p.V732L | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV71674465; called by muse, mutect2
- FBXO31 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs187880966; called by mutect2, varscan2
- FLG | c.8446C>T p.H2816Y | Missense Mutation (SNP) | VAF 63/663 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV64235782; called by muse, mutect2, varscan2
- FSCN2 | c.107C>G p.S36W | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1555670532; called by muse, mutect2
- FSCN3 | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56171158; called by muse, mutect2
- FYB1 | c.159T>G p.N53K | Missense Mutation (SNP) | VAF 82/340 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs948244346; called by muse, varscan2
- GABRA6 | c.1361A>G p.*454Wext*7 | Nonstop Mutation (SNP) | VAF 31/159 reads (19%) | catalogued as rs1347094779, COSV50880828; called by muse, mutect2, varscan2
- GABRB3 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV54662576; called by muse, mutect2, varscan2
- GPM6A | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54541548; called by muse, varscan2
- GRIA1 | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 24/198 reads (12%) | catalogued as COSV53596808, COSV53598294; called by muse, mutect2, varscan2
- HLX | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs1217699300, COSV65044998; called by muse, mutect2
- HTR1A | c.686C>A p.T229K | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.941); catalogued as COSV60501654; called by muse, mutect2, varscan2
- IARS2 | c.2441C>A p.P814H | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.903); catalogued as rs750326380; called by muse, mutect2, varscan2
- IGFN1 | c.3491G>T p.R1164L (on ENST00000295591 / NM_001367841.1; = p.R3621L on NM_001164586.2) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs371094909; called by muse, mutect2
- IGHM | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.07); catalogued as rs782792312; called by muse, mutect2, varscan2
- ILRUN | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 50/452 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV64989421; called by muse, varscan2
- IRF4 | c.1126C>A p.R376S | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV66706739; called by muse, mutect2, varscan2
- JAK2 | c.1356_1359del p.C452* | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs759468230; called by mutect2, pindel, varscan2
- KCNAB3 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs763971956; called by muse, mutect2
- KLF14 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.24); catalogued as rs782497758, COSV99081944; called by muse, mutect2, varscan2
- KLHL32 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 69/274 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs139794231, COSV65115697; called by muse, mutect2, varscan2
- LAMC3 | c.2395G>T p.G799W | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63090891; called by muse, mutect2, varscan2
- LRFN5 | c.1681C>A p.H561N | Missense Mutation (SNP) | VAF 108/429 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV53252839; called by mutect2, varscan2
- LRP1B | c.2618G>T p.G873V | Missense Mutation (SNP) | VAF 146/285 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63341875; called by muse, mutect2, varscan2
- LRRC52 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 45/371 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1331070925, COSV54233033, COSV54234146; called by muse, mutect2, varscan2
- LRRC7 | c.2092G>T p.G698W (on ENST00000651989 / NM_001370785.2; = p.G665W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50446917; called by muse, mutect2, varscan2
- MDN1 | c.1479G>T p.L493F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.222); catalogued as COSV65526567; called by muse, varscan2
- MED12L | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1361149884; called by muse, mutect2, varscan2
- MYO5C | c.4171A>G p.M1391V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs1190463916; called by muse, mutect2, varscan2
- MYO9B | c.5882G>A p.R1961Q | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs373618149; called by muse, mutect2, varscan2
- NALCN | c.2570G>T p.R857L | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs200265303; called by muse, mutect2, varscan2
- NBAS | c.3580G>A p.D1194N | Missense Mutation (SNP) | VAF 103/466 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.572); catalogued as COSV55734798; called by muse, mutect2, varscan2
- NEXMIF | c.3553G>T p.G1185W | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV50025261; called by muse, mutect2, varscan2
- NLRP13 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as rs201000741, COSV61621234; called by muse, mutect2, varscan2
- NLRP7 | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs146205567, COSV60177646; called by muse, mutect2, varscan2
- NOBOX | c.613A>G p.K205E | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs1428500486; ClinVar: uncertain significance; called by muse, varscan2
- NOLC1 | c.1401G>T p.R467S | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.01); catalogued as COSV64181287; called by muse, mutect2, varscan2
- NOX3 | c.1005del p.W335Cfs*59 | Frame Shift Del (DEL) | VAF 15/133 reads (11%) | catalogued as COSV50151690; called by mutect2, pindel, varscan2
- NPAS4 | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60650328; called by muse, mutect2, varscan2
- NPR3 | c.1200C>G p.I400M | Missense Mutation (SNP) | VAF 78/417 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54088871; called by muse, mutect2, varscan2
- OGDHL | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1167099402, COSV65104580; called by mutect2, varscan2
- OR13C8 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.485); catalogued as COSV58610692; called by muse, mutect2
- OR1Q1 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 63/353 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99939158; called by muse, mutect2, varscan2
- OR4L1 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV59851379; called by muse, varscan2
- OR4L1 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV59849311, COSV59850362; called by muse, mutect2, varscan2
- OR5T1 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 65/310 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.707); catalogued as COSV57304969; called by muse, mutect2, varscan2
- OR6P1 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 69/455 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs1412436172; called by muse, mutect2, varscan2
- OTOG | c.5593C>A p.P1865T | Missense Mutation (SNP) | VAF 57/281 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1198287048; called by muse, mutect2, varscan2
- OTUD7A | c.1489G>T p.G497C (on ENST00000307050 / NM_001382637.1; = p.G490C on NM_130901.3) | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99060800; called by muse, mutect2, varscan2
- PCDH18 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV100787522, COSV61270183; called by muse, mutect2, varscan2
- PCDH8 | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); catalogued as rs763579669; called by muse, mutect2, varscan2
- PCDHB12 | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.653); catalogued as COSV53393372; called by muse, mutect2, varscan2
- PCDHGA2 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1399656890; called by muse, mutect2, varscan2
- PCDHGA5 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.344); catalogued as rs1408140664; called by muse, mutect2, varscan2
- PCNX2 | c.3647G>T p.R1216I | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV99266841; called by muse, mutect2, varscan2
- PDHA2 | c.876G>T p.M292I | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV54777364, COSV99756551; called by muse, mutect2, varscan2
- PHOX2B | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56928816; called by muse, mutect2, varscan2
- PLCB4 | c.2365C>T p.L789F | Missense Mutation (SNP) | VAF 148/431 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs765407085, COSV53796401; called by muse, mutect2, varscan2
- POLI | c.973C>G p.Q325E | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV54190608, COSV99471288; called by muse, varscan2
- PRDM6 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as rs942024099; called by muse, mutect2, varscan2
- PRKCQ | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1274566995, COSV54106426; called by muse, mutect2, varscan2
- PTPN5 | c.823C>A p.R275S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100659775; called by muse, mutect2, varscan2
- PTPRD | c.3769C>G p.P1257A | Missense Mutation (SNP) | VAF 84/465 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs370994760; called by muse, varscan2
- RCVRN | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.826); catalogued as rs757240154, COSV99874464; called by muse, mutect2, varscan2
- RELN | c.6851C>A p.A2284D | Missense Mutation (SNP) | VAF 31/404 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59009453; called by muse, mutect2
- RIMS2 | c.1027C>G p.P343A (on ENST00000666250 / NM_001348490.2; = p.P151A on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/516 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99212632; called by muse, mutect2, varscan2
- RSRC2 | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 30/325 reads (9%) | catalogued as COSV59202950; called by muse, mutect2
- RUVBL2 | c.1027C>G p.P343A | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.303); catalogued as COSV55486496; called by muse, mutect2
- RYR2 | c.4054G>T p.G1352C | Missense Mutation (SNP) | VAF 45/313 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV100767329; called by muse, mutect2, varscan2
- SALL1 | c.1552G>T p.D518Y | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51760744; called by muse, varscan2
- SCN1A | c.3747G>T p.K1249N (on ENST00000303395 / NM_001202435.3; = p.K1238N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as CM093373; called by muse, mutect2
- SLC1A5 | c.1239G>T p.K413N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1243439083; called by muse, mutect2, varscan2
- SMARCA4 | c.390del p.S131Lfs*172 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | catalogued as COSV60796933; called by mutect2, varscan2
- SMC1A | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1429718803; called by muse, mutect2, varscan2
- SPACA9 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53766182; called by muse, mutect2
- SYNE1 | c.3925C>T p.R1309* (on ENST00000367255 / NM_182961.4; = p.R1316* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 10/202 reads (5%) | catalogued as COSV55017647; called by muse, mutect2
- SYTL3 | c.1483C>T p.R495W (on ENST00000611299 / NM_001242394.1; = p.R427W on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs142505302; called by muse, mutect2, varscan2
- TANC2 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as rs770485904; called by muse, mutect2, varscan2
- TARS1 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 131/454 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV54309277; called by muse, mutect2, varscan2
- TEAD4 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs770424147; called by muse, mutect2, varscan2
- TGDS | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as rs781446713; called by muse, mutect2, varscan2
- TMC3 | c.313-1G>T p.X105_splice | Splice Site (SNP) | VAF 52/210 reads (25%) | catalogued as COSV100845846; called by muse, mutect2, varscan2
- TMEM179B | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs751761737; called by muse, mutect2, varscan2
- TMEM232 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.242); catalogued as rs1220847202; called by muse, mutect2, varscan2
- TNFRSF10D | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs560938180, COSV100441692; called by muse, mutect2, varscan2
- TNS4 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs140763191; called by muse, mutect2
- TP53 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 78/461 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, mutect2, varscan2
- TWF1 | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV57300559; called by muse, mutect2
- TWIST1 | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1251636952; called by muse, mutect2, varscan2
- TXNDC11 | c.2411C>T p.P804L (on ENST00000356957 / NM_001303447.2; = p.P777L on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs146365481; called by muse, mutect2, varscan2
- USH2A | c.11151G>C p.L3717F | Missense Mutation (SNP) | VAF 85/412 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56325172; called by muse, mutect2, varscan2
- WFDC13 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 72/233 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199777220; called by muse, mutect2, varscan2
- ZNF25 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 46/234 reads (20%) | catalogued as COSV56923084; called by muse, mutect2, varscan2
- ZNF396 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs753172094, COSV100108496; called by muse, mutect2
- ZNF407 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 16/263 reads (6%) | catalogued as COSV55265460; called by muse, mutect2
- ZNF577 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 54/612 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs369075988; called by muse, mutect2
- AASDH | c.3062A>T p.Y1021F | Missense Mutation (SNP) | VAF 140/404 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ABRAXAS2 | c.1227C>A p.N409K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.602); called by muse, varscan2
- AC005324.2 | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ACSM5 | c.1437-2A>T p.X479_splice | Splice Site (SNP) | VAF 24/135 reads (18%) | called by muse, mutect2, varscan2
- ACSM5 | c.1437-1G>T p.X479_splice | Splice Site (SNP) | VAF 24/139 reads (17%) | called by muse, mutect2, varscan2
- ACVR1C | c.1470C>A p.D490E | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ADAMTS2 | c.3463C>T p.H1155Y | Missense Mutation (SNP) | VAF 39/361 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADCY2 | c.1571G>T p.S524I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.222); called by muse, mutect2
- ADGRG4 | c.7155T>A p.N2385K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADNP2 | c.719A>C p.H240P | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AHNAK2 | c.7049C>T p.A2350V | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- ALDH1L2 | c.2030A>C p.K677T | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- ANKDD1A | c.290T>G p.L97R | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANO2 | c.1907T>G p.F636C (on ENST00000356134 / NM_001278597.3; = p.F640C on NM_001278596.3) | Missense Mutation (SNP) | VAF 109/248 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- AP3B2 | c.3007G>C p.E1003Q (on ENST00000261722; = p.E997Q on NM_004644.5) | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ARFGEF3 | c.2498A>G p.Q833R | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ARHGAP9 | c.1501+2T>C p.X501_splice (on ENST00000393797 / NM_001319850.2; = p.X482_splice on NM_032496.4) | Splice Site (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- ARNT | c.2002G>T p.G668C | Missense Mutation (SNP) | VAF 23/344 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ARRB2 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ATR | c.3808G>T p.E1270* | Nonsense Mutation (SNP) | VAF 41/200 reads (21%) | called by muse, varscan2
- ATR | c.3807G>T p.Q1269H | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.299); called by muse, varscan2
- BAZ2A | c.631A>T p.S211C | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- BCAP31 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 46/107 reads (43%) | called by muse, mutect2, varscan2
- BCAS3 | c.661+2T>C p.X221_splice | Splice Site (SNP) | VAF 59/237 reads (25%) | called by muse, mutect2, varscan2
- BOLA1 | c.218T>A p.V73E | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BPIFB6 | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRINP3 | c.1036A>T p.T346S | Missense Mutation (SNP) | VAF 61/329 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1orf105 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C2orf16 | c.674C>G p.S225* | Nonsense Mutation (SNP) | VAF 58/283 reads (20%) | called by muse, mutect2, varscan2
- C2orf16 | c.431C>G p.P144R | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- C9orf152 | c.615G>C p.K205N | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); called by muse, mutect2
- CACNA1C | c.4477C>A p.H1493N | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CAMK4 | c.386+1G>T p.X129_splice | Splice Site (SNP) | VAF 41/156 reads (26%) | called by muse, mutect2, varscan2
- CCDC180 | c.3562G>T p.D1188Y | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CCDC181 | c.818C>A p.T273K | Missense Mutation (SNP) | VAF 105/334 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CDC23 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CENPJ | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | called by muse, varscan2
- CEP170 | c.3028C>A p.Q1010K | Missense Mutation (SNP) | VAF 34/650 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2
- CFAP57 | c.3310C>A p.Q1104K (on ENST00000372492 / NM_001378189.1; = p.Q1137K on NM_001195831.3) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CFAP65 | c.735C>G p.I245M | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CHIC1 | c.526A>T p.K176* | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- CHRM2 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 44/593 reads (7%) | called by muse, mutect2
- CLCN1 | c.1888C>A p.Q630K | Missense Mutation (SNP) | VAF 119/373 reads (32%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- CLIP4 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- COL11A1 | c.2340G>T p.K780N | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL14A1 | c.2863C>A p.L955I | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL19A1 | c.206T>C p.F69S | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2
- COL20A1 | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- COL24A1 | c.3139G>T p.G1047C | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COQ10B | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); called by muse, varscan2
- CREB3L3 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSHL1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 54/386 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CSRP3 | c.302C>A p.S101* | Nonsense Mutation (SNP) | VAF 117/587 reads (20%) | called by muse, mutect2, varscan2
- CTR9 | c.2761G>T p.V921F | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CWH43 | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYP1A1 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- DAB2 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 84/434 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCHS1 | c.8776G>T p.A2926S | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DDB2 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 119/457 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DENND5B | c.1216C>A p.P406T | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- DHX16 | c.1125G>A p.E375= | Splice Region (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- DNAH8 | c.3784G>T p.V1262L | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DNAI4 | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- DNAJC13 | c.1110del p.F370Lfs*21 | Frame Shift Del (DEL) | VAF 43/252 reads (17%) | called by mutect2, pindel, varscan2
- DOCK3 | c.4306G>C p.D1436H | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); called by muse, mutect2
- DOT1L | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- DPP10 | c.1853G>T p.R618I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- DPRX | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DPYD | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 82/359 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DRAM1 | c.671A>T p.Q224L | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DSC1 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYSF | c.4706A>T p.Q1569L | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, varscan2
- EIF2AK4 | c.2023del p.L675Wfs*22 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- ELAC2 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 36/372 reads (10%) | called by muse, mutect2
- ERAL1 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EYS | c.1859G>A p.C620Y | Missense Mutation (SNP) | VAF 60/371 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- EYS | c.759C>G p.C253W | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM200B | c.1593A>C p.L531F | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2
- FAM83B | c.2454G>T p.K818N | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FBXO5 | c.170A>G p.H57R | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FCRL3 | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 178/724 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- FCRLB | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- FGD1 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FGF13 | c.402G>T p.S134= | Splice Region (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- FOXO1 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FRMD5 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FRMPD4 | c.3756del p.G1255Afs*2 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- FSCN3 | c.1430C>A p.A477D | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2
- FSIP2 | c.1991C>T p.T664I | Missense Mutation (SNP) | VAF 108/290 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, varscan2
- GABRG1 | c.953C>A p.T318K | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAP43 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2
- GDF2 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- GFAP | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- GIMAP5 | c.297C>G p.N99K | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- GPX8 | c.512T>A p.V171D | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRID2 | c.800A>T p.D267V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- GRIN3A | c.161A>T p.H54L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GUCY2D | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- H2BC5 | c.381A>T p.*127Yext*13 (on ENST00000289316 / NM_138720.2; = p.*127Yext*23 on NM_021063.4) | Nonstop Mutation (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- HAUS3 | c.43G>C p.G15R | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- HELZ2 | c.4901C>T p.A1634V (on ENST00000467148 / NM_001037335.2; = p.A1065V on NM_033405.3) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- HMCN2 | c.14983C>A p.R4995S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HOXA1 | c.113A>T p.Q38L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- HSD17B13 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2
- HYDIN | c.11774G>T p.C3925F | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL26 | c.426T>G p.Y142* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- IL33 | c.218-1G>T p.X73_splice | Splice Site (SNP) | VAF 58/130 reads (45%) | called by muse, mutect2, varscan2
- IQGAP2 | c.4456C>A p.L1486M | Missense Mutation (SNP) | VAF 86/312 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- JADE3 | c.1456T>A p.C486S | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- JOSD1 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2
- JPH1 | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNG3 | c.1113G>T p.M371I | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KCNH6 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- KDR | c.2345T>G p.L782R | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- KLHL29 | c.2614A>G p.I872V | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.777); called by muse, mutect2
- KLK1 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- KPTN | c.579G>C p.E193D | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- LAMA1 | c.3059C>T p.T1020I | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- LAMB2 | c.2308A>T p.I770F | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LAMP5 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- LCE2C | c.192C>A p.C64* | Nonsense Mutation (SNP) | VAF 28/157 reads (18%) | called by muse, mutect2, varscan2
- LMNA | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 38/337 reads (11%) | called by muse, mutect2, varscan2
- LRFN5 | c.1682A>T p.H561L | Missense Mutation (SNP) | VAF 108/441 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- LRP6 | c.1660A>T p.S554C | Missense Mutation (SNP) | VAF 48/540 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2
- LRRC59 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEA11 | c.281T>A p.I94N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- MARS1 | c.1322G>T p.C441F | Missense Mutation (SNP) | VAF 45/316 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED1 | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- MED12L | c.3194G>T p.G1065V | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED13L | c.866A>T p.Q289L | Missense Mutation (SNP) | VAF 150/596 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MEF2C | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIB1 | c.909-1G>A p.X303_splice | Splice Site (SNP) | VAF 18/100 reads (18%) | called by muse, varscan2
- MRM1 | c.159T>G p.F53L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MROH8 | c.1426T>C p.S476P | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSH4 | c.2548G>A p.V850M | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MTCL1 | c.4436G>T p.S1479I (on ENST00000306329 / NM_001378206.1; = p.S1160I on NM_015210.4) | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MUC17 | c.10297T>C p.S3433P | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- MYH4 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- N4BP2 | c.415A>T p.T139S | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2
- NBN | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NES | c.2069G>T p.R690I | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- NFKB1 | c.1808G>T p.R603M (on ENST00000394820 / NM_001382627.1; = p.R604M on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/351 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- NLGN1 | c.1766G>C p.G589A | Missense Mutation (SNP) | VAF 41/311 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NLRP5 | c.3096G>C p.M1032I | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2
- NTRK1 | c.1249G>T p.G417W | Missense Mutation (SNP) | VAF 113/519 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- NYAP1 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- OBSCN | c.2174A>T p.Q725L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- OR10R2 | c.402del p.L135Wfs*3 | Frame Shift Del (DEL) | VAF 101/678 reads (15%) | called by mutect2, pindel, varscan2
- OR10W1 | c.623C>A p.S208Y | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OR11L1 | c.36del p.Q13Sfs*3 | Frame Shift Del (DEL) | VAF 14/95 reads (15%) | called by mutect2, pindel, varscan2
- OR13C8 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2
- OR2AK2 | c.708del p.A237Lfs*9 | Frame Shift Del (DEL) | VAF 52/318 reads (16%) | called by mutect2, pindel, varscan2
- OR2M5 | c.258G>T p.L86F | Missense Mutation (SNP) | VAF 151/445 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- OR2T12 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- OR4C13 | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR4C3 | c.683C>A p.A228E | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- OR6C3 | c.730G>T p.V244F | Missense Mutation (SNP) | VAF 97/287 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OTULINL | c.344G>T p.R115M | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- OXER1 | c.869C>G p.P290R | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PCDHA12 | c.2014A>G p.N672D | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PCDHAC1 | c.2299A>T p.N767Y | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PDE4A | c.422A>C p.Q141P | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PDILT | c.1613_1620del p.L538Hfs*19 | Frame Shift Del (DEL) | VAF 82/448 reads (18%) | called by mutect2, pindel, varscan2
- PDZD7 | c.1024C>A p.L342M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.172); called by muse, varscan2
- PEG3 | c.4073A>T p.E1358V | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PEG3 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- PELO | c.596T>G p.F199C | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PINX1 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 74/384 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIWIL1 | c.98T>A p.I33N | Missense Mutation (SNP) | VAF 27/403 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.023); called by muse, mutect2
- PKD1 | c.4894A>C p.I1632L | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.124); called by muse, mutect2
- PKP1 | c.1727C>A p.T576K | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLBD2 | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PLD1 | c.666-2A>C p.X222_splice | Splice Site (SNP) | VAF 77/255 reads (30%) | called by muse, mutect2, varscan2
- PLD2 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PLXNA2 | c.3766G>C p.V1256L | Missense Mutation (SNP) | VAF 73/354 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PNLIP | c.1022A>T p.K341I | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2
- PRDM8 | c.467C>G p.T156R | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- PRPF4B | c.2444A>G p.D815G | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPRD | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.521); called by muse, varscan2
- PTPRD | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 18/365 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.405); called by muse, mutect2
- RAB40A | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RAB6C | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBFOX1 | c.291del p.G98Vfs*53 | Frame Shift Del (DEL) | VAF 23/119 reads (19%) | called by mutect2, pindel, varscan2
- RBMS2 | c.923A>C p.H308P | Missense Mutation (SNP) | VAF 78/401 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RCOR3 | c.1009_1011del p.L337del | In Frame Del (DEL) | VAF 88/496 reads (18%) | called by mutect2, pindel, varscan2
- RELCH | c.2860G>T p.E954* | Nonsense Mutation (SNP) | VAF 70/259 reads (27%) | called by muse, varscan2
- RGS14 | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- RNASET2 | c.468A>G p.I156M | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RNF128 | c.1040del p.S347Lfs*45 (on ENST00000255499 / NM_194463.2; = p.S321Lfs*45 on NM_024539.3) | Frame Shift Del (DEL) | VAF 43/137 reads (31%) | called by mutect2, pindel, varscan2
- RNPC3 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, varscan2
- RPAP1 | c.1612G>T p.G538W | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RPAP1 | c.1351T>G p.L451V | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- RTTN | c.5242G>T p.A1748S | Missense Mutation (SNP) | VAF 22/263 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.202); called by muse, mutect2
- RYR2 | c.1564G>C p.A522P | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- RYR2 | c.8425C>G p.Q2809E | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.351); called by muse, varscan2
- SAFB2 | c.1560-2A>G p.X520_splice | Splice Site (SNP) | VAF 41/116 reads (35%) | called by muse, mutect2, varscan2
- SCUBE3 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2
- SEC23IP | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- SEC23IP | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SERPINB4 | c.973G>C p.V325L | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SIGLEC10 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2
- SLC12A1 | c.2770C>T p.L924F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SLC17A3 | c.907_913del p.A303Lfs*18 | Frame Shift Del (DEL) | VAF 103/601 reads (17%) | called by mutect2, pindel, varscan2
- SLC17A6 | c.1162A>G p.M388V | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.349); called by muse, mutect2
- SLC18A2 | c.293T>A p.L98H | Missense Mutation (SNP) | VAF 91/500 reads (18%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- SLC26A7 | c.1915A>T p.S639C | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SLC6A11 | c.953C>A p.T318N | Missense Mutation (SNP) | VAF 34/407 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLITRK2 | c.884C>A p.P295Q | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SLITRK6 | c.1572C>A p.D524E | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- SOS2 | c.1318A>G p.N440D | Missense Mutation (SNP) | VAF 82/334 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SPG11 | c.1568G>T p.W523L | Missense Mutation (SNP) | VAF 40/396 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPO11 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SRD5A2 | c.110C>G p.T37R | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- STAT1 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 40/539 reads (7%) | called by muse, mutect2
- STKLD1 | c.1823C>A p.P608Q | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUPT20HL2 | c.765C>A p.D255E | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TACC1 | c.824_825del p.T275Kfs*15 | Frame Shift Del (DEL) | VAF 13/97 reads (13%) | called by pindel, varscan2
- TCP11L2 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- TEX15 | c.2462A>C p.D821A (on ENST00000256246; = p.D1204A on NM_001350162.2) | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TG | c.6684C>A p.F2228L | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM31 | c.5G>C p.R2T | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TMPRSS11B | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2
- TNNI2 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- TNNI2 | c.341G>T p.R114M | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TNRC6B | c.5238G>T p.W1746C (on ENST00000454349 / NM_001162501.2; = p.W1636C on NM_015088.3) | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TOPAZ1 | c.4637G>A p.R1546K | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIL | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRMT1L | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRPC6 | c.2012T>A p.V671D | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TRPM4 | c.3033_3051del p.V1012Gfs*105 | Frame Shift Del (DEL) | VAF 28/262 reads (11%) | called by mutect2, pindel
- TTF1 | c.1842C>G p.N614K | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- TTLL7 | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2
- TWIST1 | c.35C>A p.P12Q | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- UNK | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- URB2 | c.1558A>G p.K520E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- VKORC1 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- VSTM2B | c.530C>G p.A177G | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWDE | c.2355G>T p.E785D | Missense Mutation (SNP) | VAF 34/463 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.395); called by muse, mutect2
- WASHC2A | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- WDR27 | c.1940C>A p.S647Y | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- WDR87 | c.5438C>A p.A1813D | Missense Mutation (SNP) | VAF 76/393 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- WSCD2 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- YLPM1 | c.5204G>T p.R1735I | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- ZIM2 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ZNF24 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 27/328 reads (8%) | called by muse, mutect2
- ZNF281 | c.779C>G p.P260R | Missense Mutation (SNP) | VAF 59/439 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF417 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- ZNF644 | c.3952T>A p.F1318I (on ENST00000337393 / NM_201269.3; = p.F96I on NM_016620.3) | Missense Mutation (SNP) | VAF 100/530 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZNF692 | c.248T>A p.L83Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF713 | c.914G>A p.G305E (on ENST00000633730 / NM_001366796.2; = p.G318E on NM_182633.3) | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF786 | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ZNF839 | c.2072A>T p.D691V (on ENST00000558850 / NM_001267827.1; = p.D807V on NM_018335.5) | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- ABCA13 | c.12756G>A p.E4252= | Silent (SNP) | VAF 36/188 reads (19%) | catalogued as rs1462673688; called by muse, mutect2, varscan2
- ABCA2 | c.6549G>T p.T2183= (on ENST00000614293; = p.T2153= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs771191807; called by muse, mutect2, varscan2
- ABCG2 | c.84G>C p.L28= | Silent (SNP) | VAF 132/405 reads (33%) | called by muse, mutect2, varscan2
- ABI3 | c.348G>A p.Q116= | Silent (SNP) | VAF 55/179 reads (31%) | called by muse, mutect2, varscan2
- ACP1 | c.375A>G p.Q125= | Silent (SNP) | VAF 10/153 reads (7%) | called by muse, mutect2
- ADAMTS20 | c.3300T>C p.D1100= | Silent (SNP) | VAF 65/356 reads (18%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4092C>A p.T1364= (on ENST00000506720 / NM_001322402.2; = p.T1253= on NM_015236.6) | Silent (SNP) | VAF 97/662 reads (15%) | called by muse, mutect2, varscan2
- AHI1 | c.2157T>C p.D719= | Silent (SNP) | VAF 18/383 reads (5%) | called by muse, mutect2
- ANGPT4 | c.1449C>T p.Y483= | Silent (SNP) | VAF 25/251 reads (10%) | called by muse, mutect2
- AXL | c.1761C>G p.V587= (on ENST00000301178 / NM_021913.5; = p.V578= on NM_001699.6) | Silent (SNP) | VAF 38/254 reads (15%) | called by muse, mutect2, varscan2
- BTBD16 | c.1131C>T p.T377= | Silent (SNP) | VAF 40/220 reads (18%) | called by muse, mutect2, varscan2
- CCDC181 | c.378T>C p.Y126= | Silent (SNP) | VAF 28/215 reads (13%) | catalogued as rs1311870878; called by muse, mutect2, varscan2
- CD1C | c.111C>A p.V37= | Silent (SNP) | VAF 55/257 reads (21%) | catalogued as COSV63807862; called by muse, mutect2, varscan2
- CNTNAP4 | c.3027C>A p.S1009= | Silent (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- CSHL1 | c.99C>G p.S33= | Silent (SNP) | VAF 53/384 reads (14%) | catalogued as COSV51990352; called by muse, mutect2, varscan2
- CTTNBP2 | c.3702C>T p.S1234= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs780731601, COSV50389650; called by muse, mutect2, varscan2
- CWH43 | c.951C>A p.T317= | Silent (SNP) | VAF 83/337 reads (25%) | called by muse, mutect2, varscan2
- CYP2C18 | c.861G>A p.L287= | Silent (SNP) | VAF 48/215 reads (22%) | called by muse, mutect2, varscan2
- DCC | c.3720C>T p.A1240= | Silent (SNP) | VAF 74/269 reads (28%) | called by muse, mutect2, varscan2
- ERICH3 | c.3609C>T p.A1203= | Silent (SNP) | VAF 38/240 reads (16%) | called by muse, mutect2, varscan2
- FAM153A | c.243A>G p.L81= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs750113172; called by muse, mutect2, varscan2
- FOLH1 | c.348G>T p.L116= | Silent (SNP) | VAF 71/357 reads (20%) | called by muse, mutect2, varscan2
- FOXG1 | c.1161G>T p.S387= | Silent (SNP) | VAF 25/200 reads (13%) | called by muse, mutect2, varscan2
- FUT11 | c.1095G>A p.L365= | Silent (SNP) | VAF 21/258 reads (8%) | catalogued as rs771511865; called by muse, mutect2
- GABRA5 | c.576C>A p.G192= | Silent (SNP) | VAF 22/199 reads (11%) | catalogued as COSV59481443; called by muse, mutect2, varscan2
- GAL3ST1 | c.1176C>A p.R392= | Silent (SNP) | VAF 7/53 reads (13%) | called by mutect2, varscan2
- GFAP | c.681C>A p.A227= | Silent (SNP) | VAF 60/184 reads (33%) | called by muse, mutect2, varscan2
- GMDS | c.951G>A p.V317= | Silent (SNP) | VAF 30/347 reads (9%) | catalogued as COSV66416762; called by muse, mutect2
- GRM5 | c.3633G>T p.S1211= (on ENST00000305447 / NM_001143831.2; = p.S1179= on NM_000842.4) | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as rs183106472; called by muse, mutect2, varscan2
- GRM5 | c.2325C>A p.A775= | Silent (SNP) | VAF 67/246 reads (27%) | called by muse, mutect2, varscan2
- HAO1 | c.312C>A p.G104= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV66491511; called by muse, mutect2, varscan2
- HCAR2 | c.357G>A p.T119= | Silent (SNP) | VAF 28/406 reads (7%) | catalogued as rs761348052; called by muse, mutect2
- HCFC1 | c.5745G>T p.V1915= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, varscan2
- HLX | c.624C>G p.P208= | Silent (SNP) | VAF 16/102 reads (16%) | called by mutect2, varscan2
- HMGCS2 | c.168C>T p.I56= | Silent (SNP) | VAF 67/167 reads (40%) | catalogued as rs1051817360; called by muse, mutect2, varscan2
- HTR3C | c.1020C>A p.P340= | Silent (SNP) | VAF 56/178 reads (31%) | catalogued as rs1199779866, COSV100570756; called by muse, mutect2, varscan2
- INPP5B | c.672C>T p.V224= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs766429146; called by muse, mutect2, varscan2
- IQGAP1 | c.3477G>C p.G1159= | Silent (SNP) | VAF 84/314 reads (27%) | called by muse, mutect2, varscan2
- IRX2 | c.96C>T p.R32= | Silent (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- ITGAM | c.2121G>T p.G707= (on ENST00000648685 / NM_001145808.2; = p.G706= on NM_000632.4) | Silent (SNP) | VAF 36/155 reads (23%) | called by muse, mutect2, varscan2
- ITGAX | c.1641G>A p.E547= | Silent (SNP) | VAF 48/200 reads (24%) | called by muse, mutect2, varscan2
- ITIH5 | c.705C>A p.A235= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2, varscan2
- KATNIP | c.3444G>T p.G1148= | Silent (SNP) | VAF 40/227 reads (18%) | called by muse, mutect2, varscan2
- KCNU1 | c.873C>A p.T291= | Silent (SNP) | VAF 74/210 reads (35%) | catalogued as rs771799388; called by muse, mutect2, varscan2
- LORICRIN | c.411C>A p.S137= | Silent (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- LPA | c.2751C>T p.T917= | Silent (SNP) | VAF 48/502 reads (10%) | called by muse, mutect2
- LRFN1 | c.1650C>G p.V550= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- LSAMP | c.414C>T p.S138= | Silent (SNP) | VAF 31/277 reads (11%) | called by muse, mutect2, varscan2
- LYPD2 | c.21G>T p.A7= | Silent (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- MAD2L2 | c.114C>T p.P38= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as rs759283688, COSV52417016; called by muse, mutect2, varscan2
- MPPED1 | c.561G>A p.L187= | Silent (SNP) | VAF 23/187 reads (12%) | called by muse, mutect2, varscan2
- MSGN1 | c.375G>T p.R125= | Silent (SNP) | VAF 61/195 reads (31%) | called by muse, mutect2, varscan2
- MYO7A | c.1626G>A p.K542= | Silent (SNP) | VAF 58/330 reads (18%) | catalogued as COSV68684048; called by muse, mutect2, varscan2
- NARS1 | c.6G>C p.V2= | Silent (SNP) | VAF 22/285 reads (8%) | called by muse, mutect2
- NEUROG1 | c.168C>A p.S56= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- NOL4 | c.342G>T p.S114= | Silent (SNP) | VAF 28/352 reads (8%) | called by muse, mutect2
- NOLC1 | c.1363C>T p.L455= | Silent (SNP) | VAF 43/242 reads (18%) | called by muse, mutect2, varscan2
- NOTCH2 | c.3249A>G p.A1083= | Silent (SNP) | VAF 163/521 reads (31%) | called by muse, mutect2, varscan2
- NOTCH2 | c.3189G>T p.L1063= | Silent (SNP) | VAF 169/615 reads (27%) | called by muse, mutect2, varscan2
- OR10W1 | c.624C>A p.S208= | Silent (SNP) | VAF 32/230 reads (14%) | catalogued as COSV101223754; called by muse, mutect2, varscan2
- OR1F1 | c.849C>A p.P283= | Silent (SNP) | VAF 49/264 reads (19%) | called by muse, mutect2, varscan2
- OR2A5 | c.675C>A p.I225= | Silent (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- OR4A15 | c.885C>A p.A295= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV59034307; called by muse, mutect2, varscan2
- OR4C12 | c.828G>C p.V276= | Silent (SNP) | VAF 29/208 reads (14%) | called by muse, mutect2, varscan2
- OR4N2 | c.615G>T p.L205= | Silent (SNP) | VAF 28/389 reads (7%) | called by muse, mutect2
- OR51G1 | c.618C>A p.A206= | Silent (SNP) | VAF 89/453 reads (20%) | called by muse, mutect2, varscan2
- OR52A1 | c.144G>A p.L48= | Silent (SNP) | VAF 36/172 reads (21%) | called by muse, mutect2, varscan2
- OR52E2 | c.717C>A p.L239= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV58613198; called by muse, mutect2, varscan2
- PAPOLA | c.1236A>T p.T412= | Silent (SNP) | VAF 83/447 reads (19%) | catalogued as rs1268809007; called by muse, mutect2, varscan2
- PCDH1 | c.3153G>A p.Q1051= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs1036292937; called by muse, mutect2, varscan2
- PCDHA5 | c.1611C>T p.R537= | Silent (SNP) | VAF 29/185 reads (16%) | catalogued as COSV65351753; called by muse, mutect2, varscan2
- PCDHGA3 | c.1170G>T p.L390= | Silent (SNP) | VAF 45/208 reads (22%) | called by muse, mutect2, varscan2
- PCYT2 | c.1149G>T p.G383= | Silent (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- PDE6C | c.1929G>A p.Q643= | Silent (SNP) | VAF 66/336 reads (20%) | called by muse, mutect2, varscan2
- PHLDB1 | c.3231A>T p.P1077= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, varscan2
- PIF1 | c.1800G>T p.A600= | Silent (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- PITRM1 | c.1227C>T p.D409= | Silent (SNP) | VAF 58/334 reads (17%) | called by muse, mutect2, varscan2
- PKHD1 | c.4500C>T p.T1500= | Silent (SNP) | VAF 34/196 reads (17%) | called by muse, mutect2, varscan2
- PRMT6 | c.966C>A p.L322= | Silent (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- PRSS8 | c.90G>C p.A30= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as rs375948962; called by mutect2, varscan2
- PTPRD | c.3852C>T p.V1284= | Silent (SNP) | VAF 62/358 reads (17%) | called by muse, varscan2
- RAB27B | c.636A>T p.P212= | Silent (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- REC114 | c.135G>T p.G45= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2
- RELCH | c.2859G>T p.V953= | Silent (SNP) | VAF 70/258 reads (27%) | called by muse, varscan2
- RYR2 | c.7308C>A p.I2436= | Silent (SNP) | VAF 39/309 reads (13%) | called by muse, mutect2, varscan2
- RYR2 | c.12534C>T p.N4178= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as rs1450929982, COSV100767427, COSV63670411; called by muse, mutect2
- SCARF2 | c.1347G>T p.L449= | Silent (SNP) | VAF 50/177 reads (28%) | catalogued as COSV56732962; called by muse, mutect2, varscan2
- SDK1 | c.6138G>A p.G2046= | Silent (SNP) | VAF 30/147 reads (20%) | called by muse, mutect2, varscan2
- SEMG2 | c.90C>A p.G30= | Silent (SNP) | VAF 36/121 reads (30%) | called by muse, mutect2, varscan2
- SLC26A7 | c.1659C>A p.S553= | Silent (SNP) | VAF 28/263 reads (11%) | called by muse, mutect2
- SLC2A14 | c.900C>T p.L300= | Silent (SNP) | VAF 73/189 reads (39%) | catalogued as rs267603693; called by muse, mutect2, varscan2
- SLC39A13 | c.192G>A p.R64= | Silent (SNP) | VAF 29/188 reads (15%) | called by muse, mutect2, varscan2
- SLC8A1 | c.1485C>G p.L495= | Silent (SNP) | VAF 67/290 reads (23%) | catalogued as COSV100244686; called by muse, mutect2, varscan2
- SMARCA2 | c.765C>A p.A255= | Silent (SNP) | VAF 16/119 reads (13%) | called by muse, mutect2, varscan2
- SNX4 | c.96C>T p.G32= | Silent (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- SOHLH1 | c.933C>A p.P311= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV100040253; called by muse, mutect2, varscan2
- SPATA16 | c.1293G>A p.K431= | Silent (SNP) | VAF 92/463 reads (20%) | called by muse, mutect2, varscan2
- SPPL2C | c.1191C>T p.T397= | Silent (SNP) | VAF 9/194 reads (5%) | called by muse, mutect2
- SRCIN1 | c.138C>T p.N46= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1271676711; called by muse, mutect2, varscan2
- TAS2R41 | c.507C>A p.T169= | Silent (SNP) | VAF 60/194 reads (31%) | called by muse, mutect2, varscan2
- TERT | c.1224C>G p.L408= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs1277442393; called by mutect2, varscan2
- TMEM200C | c.642C>T p.R214= | Silent (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- TMEM94 | c.3418C>T p.L1140= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as rs1252736473; called by muse, mutect2
- TPH1 | c.432T>G p.R144= | Silent (SNP) | VAF 69/331 reads (21%) | called by muse, mutect2, varscan2
- TRPV2 | c.1461G>A p.L487= | Silent (SNP) | VAF 27/233 reads (12%) | called by muse, mutect2, varscan2
- TTC30A | c.1236A>T p.A412= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as COSV63100498; called by muse, mutect2, varscan2
- USH2A | c.4851T>A p.A1617= | Silent (SNP) | VAF 23/263 reads (9%) | catalogued as COSV100229471, COSV56338916, COSV56351150, COSV56369282; called by muse, mutect2
- USH2A | c.4035T>A p.A1345= | Silent (SNP) | VAF 37/237 reads (16%) | called by muse, mutect2, varscan2
- VPS50 | c.37C>T p.L13= | Silent (SNP) | VAF 20/299 reads (7%) | called by muse, mutect2
- VSTM5 | c.348C>A p.G116= | Silent (SNP) | VAF 66/229 reads (29%) | called by muse, mutect2, varscan2
- VWDE | c.4305G>A p.S1435= | Silent (SNP) | VAF 33/463 reads (7%) | catalogued as rs756542750; called by muse, mutect2
- YAF2 | c.315G>A p.L105= | Silent (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- ZNF184 | c.483A>G p.P161= | Silent (SNP) | VAF 42/303 reads (14%) | catalogued as COSV53004694; called by muse, mutect2, varscan2
- ZNF235 | c.2004T>A p.A668= | Silent (SNP) | VAF 22/127 reads (17%) | called by muse, mutect2, varscan2
- ZNF45 | c.132G>T p.V44= | Silent (SNP) | VAF 33/138 reads (24%) | called by muse, mutect2, varscan2
- ZNF469 | c.525C>A p.A175= | Silent (SNP) | VAF 47/202 reads (23%) | called by muse, mutect2, varscan2
- AC002511.3 | n.325-136C>A | Intron (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3717G>A | RNA (SNP) | VAF 25/227 reads (11%) | catalogued as rs758472227; called by muse, mutect2
- AGMO | c.1263+7101C>A | Intron (SNP) | VAF 56/212 reads (26%) | called by muse, varscan2
- AL132796.2 | n.532T>C | RNA (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.750G>C | RNA (SNP) | VAF 41/204 reads (20%) | called by muse, mutect2, varscan2
- ARPP21 | c.795+416C>G | Intron (SNP) | VAF 107/254 reads (42%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1448-129C>T | Intron (SNP) | VAF 85/357 reads (24%) | called by muse, mutect2, varscan2
- C16orf86 | c.103-9C>T | Intron (SNP) | VAF 74/286 reads (26%) | called by muse, mutect2, varscan2
- C3orf20 | c.*1C>T | 3'UTR (SNP) | VAF 91/182 reads (50%) | called by muse, mutect2, varscan2
- CCN6 | c.346+40C>A | Intron (SNP) | VAF 66/214 reads (31%) | called by muse, mutect2, varscan2
- CCNYL2 | n.1352G>T | RNA (SNP) | VAF 43/217 reads (20%) | called by muse, mutect2, varscan2
- CHID1 | chr11:914559 C>T | 5'Flank (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*524G>A | 3'UTR (SNP) | VAF 22/86 reads (26%) | catalogued as rs747687002; called by muse, mutect2, varscan2
- COX4I1 | c.374-12C>G | Intron (SNP) | VAF 66/325 reads (20%) | catalogued as rs1392237578; called by muse, mutect2, varscan2
- CST9LP1 | n.385G>C | RNA (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
- CUX1 | chr7:101815999 C>A | 5'Flank (SNP) | VAF 31/225 reads (14%) | catalogued as COSV99473586; called by muse, mutect2, varscan2
- EPS8 | c.736+47G>T | Intron (SNP) | VAF 83/239 reads (35%) | called by muse, mutect2, varscan2
- FAM76B | c.-1G>C | 5'UTR (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- FLJ40288 | n.618G>T | RNA (SNP) | VAF 74/223 reads (33%) | called by muse, mutect2, varscan2
- FOXL2NB | c.221-72C>A | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs919373698; called by muse, mutect2
- G6PC3 | c.535+31G>C | Intron (SNP) | VAF 41/231 reads (18%) | called by muse, mutect2, varscan2
- GATA3 | c.*14G>C | 3'UTR (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- GCOM1 | c.1305-16801A>G | Intron (SNP) | VAF 33/179 reads (18%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | chr7:73269200 G>C | 5'Flank (SNP) | VAF 24/488 reads (5%) | called by muse, mutect2
- GTF3C5 | c.1167+54G>T | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- HDAC9 | c.2577+25C>A | Intron (SNP) | VAF 72/261 reads (28%) | catalogued as COSV67769803; called by muse, mutect2, varscan2
- HFE | c.*224C>T | 3'UTR (SNP) | VAF 62/389 reads (16%) | called by muse, mutect2, varscan2
- HLA-J | n.855G>A | RNA (SNP) | VAF 99/345 reads (29%) | catalogued as rs751594522; called by muse, mutect2, varscan2
- HNRNPA3P1 | n.224C>A | RNA (SNP) | VAF 38/191 reads (20%) | called by muse, mutect2, varscan2
- HOXC13 | c.-3G>A | 5'UTR (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- HOXD11 | c.-6G>A | 5'UTR (SNP) | VAF 23/193 reads (12%) | catalogued as rs780869059; called by muse, mutect2, varscan2
- IL18 | c.91+9G>C | Intron (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- IPO4 | c.2064-9T>A | Intron (SNP) | VAF 19/340 reads (6%) | called by muse, mutect2
- KIF28P | n.2630G>A | RNA (SNP) | VAF 44/306 reads (14%) | catalogued as rs749437742; called by muse, mutect2, varscan2
- LINC01565 | n.1074A>T | RNA (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- LINC01600 | n.807G>A | RNA (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- LYPD3 | c.382+48C>T | Intron (SNP) | VAF 18/92 reads (20%) | catalogued as rs1048729121; called by muse, mutect2
- MACF1 | c.543+11563T>G | Intron (SNP) | VAF 32/454 reads (7%) | called by muse, mutect2
- MIR30C2 | n.60G>A | RNA (SNP) | VAF 15/169 reads (9%) | called by muse, mutect2
- MTRNR2L10 | c.*11C>A | 3'UTR (SNP) | VAF 44/96 reads (46%) | catalogued as COSV71256961; called by muse, mutect2, varscan2
- NABP2 | c.-23-21C>T | Intron (SNP) | VAF 12/81 reads (15%) | called by muse, varscan2
- NCAN | c.*68G>T | 3'UTR (SNP) | VAF 49/223 reads (22%) | catalogued as COSV99386993; called by muse, mutect2, varscan2
- NDEL1 | c.-124G>T | 5'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2
- NIBAN1 | c.*91A>T | 3'UTR (SNP) | VAF 13/216 reads (6%) | called by muse, mutect2
- OR10Z1 | chr1:158611430 C>G | 3'Flank (SNP) | VAF 26/198 reads (13%) | called by muse, varscan2
- PDGFRA | c.-13+10687C>A | Intron (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- PDPK1 | c.24+549T>C | Intron (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- PEX19 | c.*488C>T | 3'UTR (SNP) | VAF 22/138 reads (16%) | catalogued as rs1441338180; called by muse, mutect2, varscan2
- SHBG | c.111+35G>T | Intron (SNP) | VAF 49/200 reads (25%) | called by muse, mutect2, varscan2
- SUPT5H | chr19:39439838 C>A | 5'Flank (SNP) | VAF 13/53 reads (25%) | catalogued as rs754478199; called by muse, mutect2, varscan2
- TBCE | c.1210+43C>T | Intron (SNP) | VAF 31/378 reads (8%) | catalogued as rs756235800; called by muse, mutect2
- TMEM135 | chr11:87037917 del C | 5'Flank (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- TMEM182 | chr2:102758423 G>T | 5'Flank (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- TPP2 | c.-30T>C | 5'UTR (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
- TSPAN18 | c.-10-8633C>G | Intron (SNP) | VAF 34/189 reads (18%) | called by muse, mutect2
- UACA | c.78+9216C>A | Intron (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2
- UBTFL2 | n.49G>C | RNA (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2
- VAPB | c.*2823G>T | 3'UTR (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- WDR49 | c.-197A>G | 5'UTR (SNP) | VAF 16/132 reads (12%) | catalogued as rs748978654; called by muse, varscan2
- YBX3 | c.878+498C>A | Intron (SNP) | VAF 12/145 reads (8%) | called by muse, mutect2
- ZNF658B | n.2333G>T | RNA (SNP) | VAF 26/84 reads (31%) | called by mutect2, varscan2
